Somatic mutation profile of tumor specimen C3L-06421-02 (aliquot CPT0373400006) from CPTAC case C3L-06421, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 52.0 years (18,981 days).
Specimen C3L-06421-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0fe51df-f711-474b-b1ab-0e5638a71bf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06421-31 (Blood Derived Normal), aliquot CPT0374630005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7428c16-78c3-4baf-9bec-c9b1a814a244

The open-access MAF lists 142 somatic variants for this specimen: 112 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 25, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, Intron 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PREX2 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 55/307 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2, varscan2
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.2711A>C p.K904T | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs568958735; called by muse, mutect2, varscan2
- ADGRB3 | c.2921T>G p.I974S | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV53258738; called by muse, mutect2, varscan2
- ASXL2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55454143; called by muse, mutect2
- BCAN | c.1922T>A p.V641E | Missense Mutation (SNP) | VAF 195/465 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.617); catalogued as COSV61255927; called by muse, mutect2, varscan2
- CHST6 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 96/339 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1466390426, COSV59999968; called by muse, mutect2, varscan2
- COBLL1 | c.1024C>T p.Q342* (on ENST00000392717; = p.Q304* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 26/392 reads (7%) | catalogued as COSV52070733; called by muse, mutect2
- CYRIA | c.637A>C p.T213P | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as COSV62864922; called by muse, mutect2, varscan2
- DCHS2 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100251246, COSV59724400; called by muse, mutect2, varscan2
- DLGAP2 | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV70101798; called by muse, mutect2
- DOCK8 | c.2486A>C p.N829T | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV66617319; called by muse, mutect2, varscan2
- DPCD | c.87A>T p.L29F | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs1298695214; called by muse, mutect2, varscan2
- DPY19L3 | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV60475702; called by muse, mutect2, varscan2
- FAT3 | c.7194T>G p.I2398M | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV53123992; called by muse, mutect2, varscan2
- FAXC | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV67601823; called by muse, mutect2, varscan2
- FGB | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122550; called by muse, mutect2, varscan2
- GABBR2 | c.2804G>T p.R935L | Missense Mutation (SNP) | VAF 93/315 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.072); catalogued as COSV52292047, COSV52316349; called by muse, mutect2, varscan2
- GNL2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs548730273; called by muse, mutect2, varscan2
- GPR26 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 107/446 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs896088887, COSV99500850; called by muse, mutect2, varscan2
- GRAMD1B | c.1510T>A p.Y504N | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100454158; called by muse, mutect2, varscan2
- GRM3 | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV64466458; called by muse, mutect2, varscan2
- HS3ST5 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV57144834; called by muse, mutect2
- HSD17B12 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs775623328; called by muse, mutect2, varscan2
- IGHJ6 | c.58T>A p.S20T | Missense Mutation (SNP) | VAF 24/200 reads (12%) | PolyPhen benign (0.411); catalogued as rs368997749; called by muse, mutect2, varscan2
- ITGA8 | c.2272T>A p.F758I | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65224372; called by muse, mutect2, varscan2
- KCNN2 | c.137C>T p.A46V (on ENST00000264773; = p.A258V on NM_021614.4) | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1194686835; called by muse, mutect2
- LAMB4 | c.4933G>A p.A1645T | Missense Mutation (SNP) | VAF 76/466 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs371803929; called by muse, mutect2, varscan2
- MAGEB18 | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57464460; called by muse, mutect2, varscan2
- MMRN1 | c.1891A>G p.K631E | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV53334327; called by muse, mutect2, varscan2
- MOB3B | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs1458774765; called by muse, mutect2, varscan2
- NLGN4X | c.2318T>C p.L773P | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.216); catalogued as COSV52011412, COSV99322018; called by muse, mutect2, varscan2
- NLRP13 | c.2405T>G p.L802R | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV61621024; called by muse, mutect2, varscan2
- NLRP9 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV60460467; called by muse, mutect2
- OR4C13 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV73648601; called by muse, mutect2, varscan2
- OR52M1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs374817370, COSV64171863; called by muse, varscan2
- PASK | c.2882T>G p.L961R | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV52157549; called by muse, mutect2, varscan2
- PCDHGA2 | c.1616A>C p.N539T | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs1561482595; called by muse, mutect2, varscan2
- PIAS2 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100245537; called by muse, mutect2
- PITX2 | c.559G>A p.A187T (on ENST00000354925 / NM_001204397.1; = p.A194T on NM_000325.6) | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs193920830, COSV60741955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB1 | c.3298C>T p.R1100W | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1458910451, COSV62036917; called by muse, mutect2, varscan2
- RBM45 | c.1306G>A p.D436N (on ENST00000616198 / NM_001365579.1; = p.D434N on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as rs748783470, COSV53721111; called by muse, mutect2, varscan2
- RTL3 | c.706T>G p.F236V | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV58183386; called by mutect2, varscan2
- RXRB | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs766468364; called by muse, mutect2, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2, varscan2
- SIM1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53496412; called by muse, mutect2
- SIX2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390790; called by muse, mutect2, varscan2
- SLC5A7 | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99886521; called by muse, mutect2, varscan2
- STX11 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV62450077; called by muse, varscan2
- SUGCT | c.1175A>C p.K392T (on ENST00000335693 / NM_001193313.2; = p.K418T on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV59334554; called by muse, mutect2, varscan2
- TBL3 | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.821); catalogued as rs752184023; called by muse, mutect2, varscan2
- TLCD1 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 36/441 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs199910670; called by muse, mutect2
- TTI2 | c.1076G>C p.R359P | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769052273; called by muse, mutect2
- UBQLNL | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66493206; called by muse, mutect2, varscan2
- WDFY4 | c.2372A>G p.K791R | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1349200129; called by muse, mutect2, varscan2
- XKR3 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs267606170, COSV58887883; called by muse, mutect2
- ZNF585B | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 164/447 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV57214688; called by muse, mutect2, varscan2
- A2M | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ADAM29 | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANHX | c.393del p.S132Pfs*7 | Frame Shift Del (DEL) | VAF 75/169 reads (44%) | called by mutect2, pindel, varscan2
- ATP10B | c.2612T>C p.M871T | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CABIN1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNG8 | c.1138G>C p.V380L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); called by muse, mutect2
- CATSPERE | c.2081A>C p.Q694P | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- CCDC86 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.165); called by muse, mutect2
- CDH9 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CHST13 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CUBN | c.5171C>A p.A1724D | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.259); called by muse, mutect2
- DCAF1 | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.112); called by muse, mutect2
- DCC | c.3487A>G p.K1163E | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- DSCAM | c.3913T>G p.L1305V | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EPB41L3 | c.974A>C p.D325A | Missense Mutation (SNP) | VAF 90/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXR2 | c.546A>C p.Q182H | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FREM1 | c.2124A>C p.K708N | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FRMD4B | c.1614C>G p.Y538* | Nonsense Mutation (SNP) | VAF 102/357 reads (29%) | called by muse, mutect2, varscan2
- FRY | c.6877C>G p.R2293G | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCKR | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GLI2 | c.4114G>C p.V1372L (on ENST00000361492 / NM_001374353.1; = p.V1389L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.1); called by muse, mutect2
- INPP5B | c.1337C>G p.A446G (on ENST00000373023; = p.A366G on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- KCNJ2 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2
- LRP1B | c.8738A>C p.K2913T | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MAGEC1 | c.3091G>A p.G1031R | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MPP7 | c.165A>C p.E55D | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MRC1 | c.1307A>C p.E436A | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYNN | c.77_78del p.C26Yfs*10 | Frame Shift Del (DEL) | VAF 39/332 reads (12%) | called by mutect2, pindel, varscan2
- PASK | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.201); called by muse, mutect2
- PBX4 | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH9 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.602); called by muse, mutect2
- PHF14 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 158/387 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PI4KA | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP1R10 | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRDM9 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PRRC2B | c.1478A>C p.K493T | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RBM20 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ROCK1 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPAP1 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); called by muse, mutect2
- RSBN1L | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTN3 | c.2354G>C p.W785S (on ENST00000377819 / NM_001265589.2; = p.W766S on NM_201428.3) | Missense Mutation (SNP) | VAF 25/415 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- RXRG | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR2 | c.6826A>C p.S2276R | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SIPA1L3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, varscan2
- STK24 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2
- STON2 | c.2455A>C p.S819R (on ENST00000649389 / NM_001366849.2; = p.S762R on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TDRP | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- THSD7B | c.4373A>C p.N1458T (on ENST00000272643; = p.N1456T on NM_001316349.2) | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRIM60 | c.219T>G p.N73K | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TTC3 | c.3022G>C p.D1008H | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VAV3 | c.2255A>G p.K752R | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WDR72 | c.2811G>C p.K937N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFR | c.1035T>C p.T345= | Splice Region (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ZNF257 | c.1407C>G p.N469K | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF474 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 36/289 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.4207A>C p.R1403= | Silent (SNP) | VAF 71/237 reads (30%) | catalogued as COSV99900442; called by muse, mutect2, varscan2
- ADCY1 | c.513C>T p.F171= | Silent (SNP) | VAF 28/585 reads (5%) | catalogued as COSV52040908; called by muse, mutect2
- C7 | c.2040T>C p.S680= | Silent (SNP) | VAF 47/283 reads (17%) | called by muse, varscan2
- CARD14 | c.1458G>A p.K486= | Silent (SNP) | VAF 50/498 reads (10%) | called by muse, mutect2
- CREB3L4 | c.663C>G p.V221= | Silent (SNP) | VAF 21/310 reads (7%) | called by muse, mutect2
- DCC | c.1512T>C p.A504= | Silent (SNP) | VAF 35/307 reads (11%) | catalogued as COSV59099589; called by muse, mutect2, varscan2
- DND1 | c.894G>A p.P298= | Silent (SNP) | VAF 32/281 reads (11%) | catalogued as rs756941934; called by muse, mutect2, varscan2
- EBF3 | c.417C>A p.I139= | Silent (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- H1-5 | c.372G>A p.K124= | Silent (SNP) | VAF 42/416 reads (10%) | catalogued as rs1235690458, COSV58901442; called by muse, mutect2
- ISX | c.666T>G p.T222= | Silent (SNP) | VAF 49/278 reads (18%) | catalogued as COSV100434109, COSV58086618; called by muse, mutect2, varscan2
- KIF21A | c.834T>G p.S278= | Silent (SNP) | VAF 45/309 reads (15%) | called by muse, mutect2, varscan2
- NYAP2 | c.1296T>C p.S432= | Silent (SNP) | VAF 44/367 reads (12%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1443C>T p.D481= | Silent (SNP) | VAF 72/466 reads (15%) | catalogued as rs781906437, COSV65342617; called by muse, mutect2, varscan2
- PCDHGA7 | c.405G>A p.T135= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as COSV53987634; called by muse, mutect2, varscan2
- PCNT | c.4356G>A p.G1452= | Silent (SNP) | VAF 42/343 reads (12%) | catalogued as rs776946965, COSV64025606; called by muse, mutect2, varscan2
- RGS22 | c.3609C>G p.G1203= | Silent (SNP) | VAF 18/364 reads (5%) | called by muse, mutect2
- SLC39A12 | c.936T>A p.S312= | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- SPG11 | c.180G>C p.A60= | Silent (SNP) | VAF 22/330 reads (7%) | catalogued as COSV99969082; called by muse, mutect2
- TOP3B | c.342G>A p.L114= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as rs1471425378; called by muse, mutect2
- TRHR | c.306T>G p.T102= | Silent (SNP) | VAF 64/371 reads (17%) | catalogued as COSV61235823; called by muse, mutect2, varscan2
- TUBA3E | c.471C>G p.L157= | Silent (SNP) | VAF 13/333 reads (4%) | called by muse, mutect2
- UGT2B28 | c.531C>A p.G177= | Silent (SNP) | VAF 21/279 reads (8%) | called by muse, mutect2
- VWCE | c.2274C>T p.H758= | Silent (SNP) | VAF 38/283 reads (13%) | catalogued as rs770129790, COSV57114823; called by muse, mutect2, varscan2
- ZHX2 | c.1047C>T p.P349= | Silent (SNP) | VAF 68/588 reads (12%) | catalogued as rs146955427; called by muse, mutect2, varscan2
- ZNF837 | c.1065G>T p.G355= | Silent (SNP) | VAF 52/302 reads (17%) | called by muse, mutect2, varscan2
- AC244258.1 | n.419G>A | RNA (SNP) | VAF 26/195 reads (13%) | catalogued as rs1327564072; called by muse, mutect2, varscan2
- ATXN8OS | n.499+1048A>C | Intron (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- C20orf197 | n.1399C>A | RNA (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- OR5R1 | chr11:56413529 A>C | 3'Flank (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2
- SHANK2 | c.1854-71G>A | Intron (SNP) | VAF 62/265 reads (23%) | called by muse, mutect2, varscan2
